Gene-level copy-number profile of tumor specimen TCGA-D1-A169-01A from TCGA case TCGA-D1-A169, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IV; Tumor grade: G2; Age at diagnosis: 63.6 years (23,238 days).
Specimen TCGA-D1-A169-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCEC.a3426ec0-6081-434b-beb4-f3e5436fa5ec.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-D1-A169-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/4d85e16c-0b65-440b-8e0b-d88d11922180

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 11,109; copy number 2: 45,599; copy number 3: 2,902; copy number 5: 10; copy number 6: 131; copy number 10: 69.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-D1-A169-01A-11D-A12G-01): tumor purity 0.67, ploidy 1.92, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 210 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:66,040,765–70,436,584, 194 genes, copy number 6–10 (broad region; genes not listed).
- chr11:70,477,277–70,706,068, 6 genes, copy number 10: AP001271.1, AP001271.2, SHANK2-AS1, SHANK2-AS2, Y_RNA, AP000590.1.
- chr18:23,992,773–24,135,610, 1 gene, copy number 5 (within-gene range 3–5): TTC39C.
- chr18:24,076,794–24,162,211, 6 genes, copy number 5: AC090772.2, AC090772.1, RNU5A-6P, AC090772.4, CABYR, AC090772.3.
- chr18:24,170,505–24,218,404, 3 genes, copy number 5: RNA5SP452, Metazoa_SRP, RNU6-435P.

Autosomal genes at a single copy (total copy number 1): 8,688. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
